Somatic mutation profile of tumor specimen TCGA-85-8354-01A (aliquot TCGA-85-8354-01A-31D-2323-08) from TCGA case TCGA-85-8354, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 53.9 years (19,692 days).
Specimen TCGA-85-8354-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d04f936f-2f7b-4a7c-86db-e681c738bdd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8354-10A (Blood Derived Normal), aliquot TCGA-85-8354-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4944210-cec7-41fa-b875-9ef558bc96bc

The open-access MAF lists 231 somatic variants for this specimen: 168 protein-altering or splice-affecting, 59 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 59, Frame Shift Del 6, Nonsense Mutation 5, Splice Site 4, Frame Shift Ins 2, Intron 2, RNA 2, In Frame Del 1, In Frame Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.6433C>T p.R2145* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as rs770558150, CM152829, COSV52514260; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993+2T>G p.X331_splice | Splice Site (SNP) | VAF 71/88 reads (81%) | hotspot (GDC flag); catalogued as COSV52703680, COSV52798259, COSV52814192; called by muse, mutect2, varscan2
- ABR | c.1849G>A p.G617R (on ENST00000302538 / NM_021962.5; = p.G580R on NM_001092.5) | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.72); catalogued as rs746240169, COSV99347926, COSV99348075; called by muse, mutect2, varscan2
- ADAM22 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99717129; called by muse, mutect2, varscan2
- ADGRF5 | c.3004C>G p.P1002A | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV99345724; called by muse, mutect2, varscan2
- AGL | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 47/425 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.784); catalogued as rs1306506074, COSV99649358; called by muse, mutect2, varscan2
- AKAP13 | c.4019A>T p.Q1340L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100773906; called by muse, mutect2
- ALKBH1 | c.753del p.A252Pfs*25 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as COSV53660778; called by mutect2, pindel, varscan2
- ALPK2 | c.509A>T p.H170L | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100864444; called by muse, mutect2, varscan2
- ALPK3 | c.3136C>T p.R1046C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs34414438; called by muse, mutect2, varscan2
- AMIGO1 | c.1471A>G p.I491V | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.437); catalogued as COSV100881071; called by muse, mutect2, varscan2
- ANKEF1 | c.1676G>T p.W559L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101001028; called by muse, mutect2, varscan2
- ANKEF1 | c.1677G>T p.W559C | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101001029; called by muse, mutect2, varscan2
- ANO3 | c.1849A>C p.I617L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.14); catalogued as COSV99883257; called by muse, mutect2
- ARHGDIG | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV99249888; called by muse, mutect2
- ATP1A2 | c.1895C>G p.S632* | Nonsense Mutation (SNP) | VAF 22/108 reads (20%) | catalogued as COSV100767876; called by muse, mutect2, varscan2
- BECN1 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV100831137; called by muse, mutect2, varscan2
- BICC1 | c.957C>G p.H319Q | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.285); catalogued as COSV54064714, COSV99570600; called by muse, mutect2, varscan2
- BORCS7 | c.304A>T p.N102Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV100185744; called by muse, mutect2, varscan2
- C17orf80 | c.1161G>C p.K387N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs557868977, COSV99278134; called by muse, varscan2
- C17orf80 | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.899); catalogued as rs369760744; called by muse, varscan2
- C5orf51 | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV101068972; called by muse, mutect2, varscan2
- CADM1 | c.398A>G p.E133G | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV100522806; called by muse, mutect2, varscan2
- CADPS | c.1793A>G p.E598G | Missense Mutation (SNP) | VAF 64/90 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99338678; called by muse, mutect2, varscan2
- CADPS | c.1505A>T p.N502I | Missense Mutation (SNP) | VAF 64/83 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV99338680; called by muse, mutect2, varscan2
- CCDC178 | c.1332G>T p.L444F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100285095, COSV55760082; called by muse, mutect2
- CCDC68 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs562337403, COSV100491853; called by muse, mutect2, varscan2
- CCDC88C | c.2183G>A p.R728K | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.91); PolyPhen benign (0.045); catalogued as COSV66239273; called by muse, mutect2, varscan2
- CD34 | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100178436; called by muse, mutect2, varscan2
- CDH10 | c.2258C>T p.S753L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100051724, COSV52584958; called by muse, mutect2, varscan2
- CDH18 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99935515, COSV99938717; called by mutect2, varscan2
- CDYL | c.725G>T p.G242V (on ENST00000328908 / NM_001368125.1; = p.G188V on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100189457, COSV59361242; called by muse, mutect2, varscan2
- CEP250 | c.3304C>T p.Q1102* | Nonsense Mutation (SNP) | VAF 34/67 reads (51%) | catalogued as COSV100698956; called by muse, varscan2
- CHD1L | c.436T>A p.F146I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV100787473; called by muse, mutect2, varscan2
- CIBAR2 | c.537+1G>T p.X179_splice | Splice Site (SNP) | VAF 13/34 reads (38%) | catalogued as COSV101608279; called by muse, mutect2, varscan2
- CLASP2 | c.686C>A p.S229* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100223552; called by muse, mutect2, varscan2
- CNTNAP4 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs1014910351, COSV56669618; called by muse, mutect2, varscan2
- CNTNAP5 | c.2648T>A p.L883H | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101443634; called by muse, mutect2, varscan2
- COL12A1 | c.6670T>C p.W2224R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100486069; called by muse, mutect2, varscan2
- COPS4 | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV100018582; called by muse, mutect2
- CP | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99224161; called by muse, mutect2, varscan2
- CPA3 | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99936196; called by muse, mutect2, varscan2
- CPVL | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55301588; called by muse, mutect2, varscan2
- CUL4B | c.345A>G p.I115M | Missense Mutation (SNP) | VAF 45/52 reads (87%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.025); catalogued as rs779144333, COSV100340639; called by muse, mutect2, varscan2
- DCC | c.355G>C p.A119P | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100500484, COSV100502334, COSV100503566; called by muse, mutect2, varscan2
- DCN | c.289A>C p.K97Q | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV99272317; called by muse, mutect2, varscan2
- DGKB | c.2089G>A p.V697I | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.87); PolyPhen benign (0.029); catalogued as COSV99340093; called by muse, mutect2, varscan2
- DISP1 | c.291C>A p.H97Q | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs759715045, COSV99450770; called by muse, mutect2, varscan2
- DNAAF5 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.599); catalogued as COSV99859885; called by muse, mutect2, varscan2
- DOT1L | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs780465036, COSV101288687; called by muse, mutect2, varscan2
- EPC1 | c.1984G>T p.A662S | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99552980; called by muse, mutect2, varscan2
- EPG5 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs142601828, COSV56354729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FFAR3 | c.844G>C p.G282R | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100588218; called by mutect2, varscan2
- FFAR3 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV100588219; called by mutect2, varscan2
- FMNL1 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100056539; called by muse, mutect2, varscan2
- GIMAP6 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 78/314 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.34); catalogued as rs142353229; called by muse, mutect2, varscan2
- GRM7 | c.736+2T>A p.X246_splice | Splice Site (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100736850; called by muse, mutect2, varscan2
- H2BC7 | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as rs1036087644, COSV100587193; called by muse, mutect2, varscan2
- HIRIP3 | c.1591G>C p.D531H | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV99663096; called by muse, mutect2, varscan2
- HIRIP3 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54229970; called by muse, varscan2
- IGHMBP2 | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as COSV99662135; called by muse, mutect2, varscan2
- IQGAP2 | c.3868G>A p.D1290N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV57173702, COSV57177592; called by muse, mutect2, varscan2
- IQSEC3 | c.3157G>T p.G1053W | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV58285866; called by muse, mutect2, varscan2
- ISL1 | c.93G>T p.R31S | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100045473; called by muse, mutect2, varscan2
- JAG2 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV100078479; called by muse, mutect2, varscan2
- JAGN1 | c.162G>C p.K54N | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV100314763; called by muse, mutect2, varscan2
- JMY | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs376180978; called by muse, mutect2, varscan2
- KEAP1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50263976, COSV50656013; called by muse, mutect2, varscan2
- KIAA0586 | c.821C>T p.S274F (on ENST00000619416 / NM_001244190.2; = p.S289F on NM_014749.5) | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV54183020; called by muse, mutect2, varscan2
- KIAA1522 | c.2615A>T p.H872L (on ENST00000373480 / NM_001198972.2; = p.H931L on NM_020888.3) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV99614705; called by muse, mutect2, varscan2
- KLHL25 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753271129, COSV61994484; called by muse, mutect2, varscan2
- KNOP1 | c.332G>T p.S111I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99575204; called by muse, mutect2, varscan2
- KPTN | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.627); catalogued as COSV99370016; called by muse, mutect2, varscan2
- KRT5 | c.1411C>G p.R471G | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as CM103084, COSV99357833; called by muse, mutect2, varscan2
- LAMA1 | c.7569C>G p.I2523M | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV101056588; called by muse, mutect2, varscan2
- LDB3 | c.1100C>G p.S367C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV99555316; called by muse, mutect2, varscan2
- MAGEB6 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs750281330, COSV66872058; called by muse, mutect2, varscan2
- MAGEC1 | c.3130C>A p.L1044I | Missense Mutation (SNP) | VAF 62/71 reads (87%) | SIFT tolerated (0.26); PolyPhen benign (0.127); catalogued as COSV99595810; called by muse, mutect2, varscan2
- MCOLN1 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs781198432, COSV51181648; called by muse, mutect2, varscan2
- MEP1B | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 187/204 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750552768, COSV99328901; called by muse, mutect2, varscan2
- MGAM | c.2938G>T p.A980S | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.32); PolyPhen benign (0.104); catalogued as COSV101527523; called by muse, mutect2, varscan2
- MGAT5B | c.140C>G p.A47G | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as COSV100048132; called by muse, mutect2, varscan2
- MSX1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV101235698; called by muse, mutect2, varscan2
- MTAP | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 91/105 reads (87%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV101205466; called by muse, mutect2, varscan2
- MUC16 | c.6503G>A p.S2168N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); catalogued as COSV101200068; called by muse, mutect2, varscan2
- MYH8 | c.273G>C p.E91D | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs148638810; called by muse, mutect2, varscan2
- MYO10 | c.5535C>A p.H1845Q | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV57018022; called by muse, mutect2, varscan2
- NDNF | c.263G>T p.W88L | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65633669; called by muse, mutect2, varscan2
- NFE2L2 | c.867C>A p.F289L | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.292); catalogued as COSV101229380; called by muse, mutect2, varscan2
- NID2 | c.3459G>C p.E1153D | Missense Mutation (SNP) | VAF 100/209 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV99356640; called by muse, mutect2, varscan2
- NOP2 | c.1334G>T p.R445L (on ENST00000322166 / NM_001258308.2; = p.R441L on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV100351162; called by muse, mutect2, varscan2
- NOS1 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs867162592, COSV57620076; called by muse, mutect2
- NUCB2 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.036); catalogued as COSV100082792; called by muse, mutect2, varscan2
- OR52K2 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as COSV100355759; called by muse, mutect2, varscan2
- OR6F1 | c.563C>A p.A188D | Missense Mutation (SNP) | VAF 73/137 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV100129230; called by muse, mutect2, varscan2
- OTOL1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100020027; called by muse, mutect2
- P2RX1 | c.1199G>C p.*400Sext*7 | Nonstop Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99340330; called by muse, mutect2, varscan2
- PCCA | c.1041C>A p.F347L | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100886885, COSV66196838; called by muse, mutect2, varscan2
- PCDHB14 | c.437C>A p.T146N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV53388601, COSV99505986; called by muse, mutect2, varscan2
- PDPR | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 89/314 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.053); catalogued as rs745837265, COSV99848418; called by muse, mutect2, varscan2
- PER2 | c.3469A>G p.N1157D | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99612051; called by muse, mutect2, varscan2
- PIK3C3 | c.1658T>C p.V553A | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as COSV100011039; called by muse, mutect2, varscan2
- PKHD1 | c.11031G>T p.M3677I | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100944365; called by muse, mutect2, varscan2
- PNPT1 | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV99570064; called by muse, mutect2, varscan2
- POTEE | c.333del p.S112Afs*55 | Frame Shift Del (DEL) | VAF 64/191 reads (34%) | catalogued as COSV58225818; called by mutect2, varscan2
- PPP1R26 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT tolerated (0.33); PolyPhen benign (0.171); catalogued as COSV100778078; called by muse, mutect2, varscan2
- PRDM9 | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV99690544; called by muse, varscan2
- PRR7 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV99446070; called by muse, mutect2, varscan2
- PSME4 | c.2933C>T p.S978L | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV101122521; called by muse, mutect2, varscan2
- PTPRG | c.673G>C p.V225L | Missense Mutation (SNP) | VAF 87/128 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV55634232, COSV99875239; called by muse, mutect2, varscan2
- PYGM | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 115/323 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs371357163; called by muse, mutect2, varscan2
- RBM5 | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 66/84 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100762318; called by muse, mutect2, varscan2
- RFX7 | c.1016C>G p.P339R (on ENST00000559447 / NM_001368074.1; = p.P436R on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100428867; called by muse, mutect2, varscan2
- RGS22 | c.3301G>C p.A1101P | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100693312; called by muse, mutect2, varscan2
- RHPN1 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV100000696; called by muse, mutect2, varscan2
- RTN1 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99955041; called by muse, mutect2, varscan2
- SCCPDH | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.984); catalogued as COSV100829733; called by muse, mutect2, varscan2
- SCN1A | c.1302G>T p.L434F | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100320690; called by muse, mutect2, varscan2
- SCN4A | c.4837G>A p.G1613S | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101438506; called by muse, mutect2, varscan2
- SDK1 | c.4420A>G p.R1474G | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV101269433; called by muse, mutect2, varscan2
- SDS | c.903C>G p.I301M | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55106350, COSV99785352; called by muse, mutect2, varscan2
- SEMA3D | c.880C>G p.R294G | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99406752; called by muse, mutect2, varscan2
- SFI1 | c.266+1G>A p.X89_splice | Splice Site (SNP) | VAF 52/120 reads (43%) | catalogued as COSV101192118; called by muse, mutect2, varscan2
- SFI1 | c.1658A>G p.Y553C (on ENST00000400288 / NM_001007467.3; = p.Y522C on NM_014775.4) | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs756683959, COSV101192119; called by muse, mutect2
- SHANK2 | c.4564G>A p.E1522K | Missense Mutation (SNP) | VAF 65/811 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs544418717, COSV53611817; called by muse, mutect2
- SLAMF6 | c.503C>A p.A168D | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.919); catalogued as COSV100924892; called by muse, mutect2, varscan2
- SLC39A10 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100660619; called by muse, mutect2, varscan2
- SLC5A7 | c.44A>G p.Y15C | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99886759; called by muse, mutect2, varscan2
- SOS1 | c.3214G>A p.E1072K | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.777); catalogued as COSV101216987; called by muse, mutect2, varscan2
- SULF2 | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100737228; called by muse, mutect2, varscan2
- SYCP2 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748171948, COSV62767522; called by muse, mutect2, varscan2
- TAS2R42 | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62084386; called by muse, mutect2
- TBC1D16 | c.1837C>G p.L613V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100188101; called by muse, mutect2, varscan2
- TDRD6 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs762607908, COSV100287717; called by muse, varscan2
- TLR9 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100564539; called by muse, mutect2, varscan2
- TMTC2 | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 41/116 reads (35%) | catalogued as COSV100338123; called by muse, mutect2, varscan2
- TNIK | c.569G>C p.G190A | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52691711, COSV99457583; called by muse, mutect2, varscan2
- TNS3 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs773597136, COSV60794227; called by muse, mutect2, varscan2
- TTN | c.48023C>A p.A16008D (on ENST00000591111; = p.A8584D on NM_003319.4) | Missense Mutation (SNP) | VAF 42/129 reads (33%) | PolyPhen benign (0.421); catalogued as COSV100615949; called by muse, mutect2, varscan2
- TTN | c.20497C>A p.P6833T (on ENST00000591111; = p.P5906T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | PolyPhen possibly damaging (0.711); catalogued as COSV100615954; called by muse, mutect2, varscan2
- TTN | c.14902G>T p.A4968S (on ENST00000591111; = p.A4041S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/252 reads (40%) | PolyPhen benign (0); catalogued as COSV100615955, COSV60113963; called by muse, mutect2, varscan2
- UBE2H | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100842481; called by muse, mutect2, varscan2
- UBR4 | c.8740C>T p.R2914W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs758640209, COSV64386018; called by muse, mutect2, varscan2
- UGGT1 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99390792; called by muse, varscan2
- VEZT | c.488G>C p.W163S | Missense Mutation (SNP) | VAF 134/447 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV99703988; called by muse, mutect2, varscan2
- VPS13A | c.1360C>G p.L454V | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as COSV100652915; called by muse, mutect2, varscan2
- VWCE | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 70/346 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs766871805, COSV57111579; called by muse, mutect2, varscan2
- WDR17 | c.3035C>T p.A1012V | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs149711744; called by muse, mutect2, varscan2
- WWP1 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as COSV99616512; called by muse, mutect2, varscan2
- XKR3 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100509283; called by muse, mutect2, varscan2
- ZBTB8A | c.1195T>A p.W399R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100331381; called by muse, mutect2, varscan2
- ZFHX3 | c.4949C>G p.S1650C | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV51725345, COSV99213019; called by muse, mutect2, varscan2
- ZFHX4 | c.1720C>A p.P574T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs780894776, COSV99263410; called by muse, mutect2, varscan2
- ZMYM6 | c.2189C>G p.S730C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100593199; called by muse, mutect2, varscan2
- ZNF431 | c.1265A>G p.H422R | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs914021700, COSV100218793; called by muse, mutect2, varscan2
- ZNF570 | c.206del p.G69Efs*7 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as COSV100356007; called by mutect2, pindel, varscan2
- ZNF804A | c.2221C>A p.L741I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.198); catalogued as COSV56473034; called by muse, mutect2
- ZZZ3 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 82/147 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100890346; called by muse, mutect2, varscan2
- AP1B1 | c.1542dup p.D515Rfs*2 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- CATSPERE | c.912del p.L305Ffs*3 | Frame Shift Del (DEL) | VAF 34/160 reads (21%) | called by mutect2, pindel, varscan2
- CDH12 | c.186dup p.V63Cfs*43 | Frame Shift Ins (INS) | VAF 58/125 reads (46%) | called by mutect2, pindel, varscan2
- DDX43 | c.52_68del p.R18Vfs*18 | Frame Shift Del (DEL) | VAF 30/173 reads (17%) | called by mutect2, pindel, varscan2
- FBXW7 | c.1068_1082del p.R357_I361del (on ENST00000281708 / NM_001349798.2; = p.R277_I281del on NM_018315.5) | In Frame Del (DEL) | VAF 70/106 reads (66%) | called by mutect2, pindel, varscan2
- NBPF11 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 65/314 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RNF130 | c.515del p.N172Tfs*6 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel, varscan2
- SLC6A19 | c.795_796insTCG p.P265_D266insS | In Frame Ins (INS) | VAF 73/141 reads (52%) | called by mutect2, pindel, varscan2
- TTN | c.31595C>A p.P10532Q (on ENST00000591111; = p.P9605Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | PolyPhen probably damaging (0.998); called by mutect2, varscan2
- WASHC2A | c.3476C>T p.A1159V | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ABCC2 | c.3888C>T p.S1296= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV100966553; called by muse, mutect2, varscan2
- ADCY1 | c.1717T>C p.L573= | Silent (SNP) | VAF 35/331 reads (11%) | catalogued as COSV52041423, COSV99812132; called by muse, mutect2
- ARHGAP35 | c.4146C>T p.V1382= | Silent (SNP) | VAF 138/264 reads (52%) | catalogued as COSV101351124; called by muse, mutect2, varscan2
- ARMC10 | c.996G>A p.V332= | Silent (SNP) | VAF 48/165 reads (29%) | catalogued as COSV100085754; called by muse, mutect2, varscan2
- ATP6V0D1 | c.63C>G p.R21= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV99341175; called by muse, mutect2, varscan2
- BEND2 | c.1185T>A p.S395= | Silent (SNP) | VAF 28/34 reads (82%) | catalogued as COSV101192053; called by muse, mutect2, varscan2
- CADPS | c.954A>G p.A318= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99338685; called by muse, mutect2, varscan2
- CD163 | c.2823T>C p.R941= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV100775868; called by muse, mutect2, varscan2
- CD28 | c.600G>A p.G200= | Silent (SNP) | VAF 57/160 reads (36%) | catalogued as COSV100142414; called by muse, mutect2, varscan2
- CKB | c.30G>C p.L10= | Silent (SNP) | VAF 28/48 reads (58%) | catalogued as COSV100818927; called by muse, mutect2, varscan2
- CLHC1 | c.885T>G p.L295= | Silent (SNP) | VAF 43/192 reads (22%) | catalogued as COSV101284900; called by muse, mutect2, varscan2
- CWC22 | c.2556A>C p.S852= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV99844323; called by muse, mutect2, varscan2
- DHX36 | c.2058G>A p.L686= | Silent (SNP) | VAF 41/267 reads (15%) | catalogued as COSV100273641; called by muse, mutect2, varscan2
- DIP2A | c.3036C>T p.T1012= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs371134930, COSV100596494; called by muse, mutect2, varscan2
- DSG3 | c.1623C>T p.I541= | Silent (SNP) | VAF 42/169 reads (25%) | catalogued as COSV57130173; called by muse, varscan2
- ELL | c.738C>A p.L246= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV99443276; called by muse, mutect2, varscan2
- EPHA2 | c.294C>G p.L98= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV64454556, COSV64454717; called by muse, mutect2, varscan2
- EVI5L | c.858C>A p.L286= | Silent (SNP) | VAF 46/195 reads (24%) | catalogued as COSV99563209; called by muse, mutect2, varscan2
- EXT1 | c.384C>T p.A128= | Silent (SNP) | VAF 55/105 reads (52%) | catalogued as COSV100983592, COSV100984021; called by muse, mutect2, varscan2
- FAM135B | c.2025C>A p.V675= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as COSV99424439; called by muse, mutect2, varscan2
- FLG | c.1335G>C p.L445= | Silent (SNP) | VAF 223/453 reads (49%) | catalogued as COSV100911628; called by muse, mutect2, varscan2
- FMNL1 | c.2409C>T p.F803= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as COSV100056542; called by muse, mutect2, varscan2
- HBB | c.33C>G p.A11= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as CD991743, CS971756, COSV100092789, COSV100092954; called by muse, mutect2
- HEPH | c.3312T>C p.N1104= (on ENST00000343002; = p.N837= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/44 reads (86%) | catalogued as COSV100294967; called by muse, mutect2, varscan2
- HMCN1 | c.11679C>G p.V3893= | Silent (SNP) | VAF 53/93 reads (57%) | catalogued as COSV54876957; called by muse, mutect2, varscan2
- IPO13 | c.396C>G p.L132= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100961230; called by muse, mutect2, varscan2
- KCNK18 | c.918A>G p.T306= | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as COSV100572061; called by muse, mutect2, varscan2
- LRRC36 | c.1242C>T p.V414= | Silent (SNP) | VAF 74/154 reads (48%) | catalogued as COSV99338763; called by muse, mutect2, varscan2
- MAGEB1 | c.615G>C p.L205= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100974996; called by muse, mutect2, varscan2
- MTCL1 | c.4626G>A p.P1542= (on ENST00000306329 / NM_001378206.1; = p.P1223= on NM_015210.4) | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as rs149764588; called by muse, mutect2, varscan2
- NFE2L2 | c.465C>G p.V155= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV101229381; called by muse, mutect2, varscan2
- NLRP1 | c.3288C>T p.N1096= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99334323; called by muse, mutect2, varscan2
- NLRP3 | c.1629C>T p.N543= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs376057645; called by muse, mutect2, varscan2
- OGDHL | c.2340G>A p.A780= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs771265292, COSV65102561; called by muse, mutect2, varscan2
- OR8D1 | c.78C>T p.P26= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs1324290344, COSV100766654; called by muse, mutect2, varscan2
- P3H2 | c.126G>A p.Q42= | Silent (SNP) | VAF 20/24 reads (83%) | catalogued as rs775441432, COSV100077813; called by muse, varscan2
- PCDHAC1 | c.2634C>T p.N878= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV99149240; called by muse, mutect2, varscan2
- PLEKHH1 | c.2745C>T p.L915= | Silent (SNP) | VAF 36/60 reads (60%) | catalogued as COSV100233174; called by muse, mutect2, varscan2
- PLXNA1 | c.3957C>A p.I1319= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV99303216; called by muse, mutect2, varscan2
- PPFIBP2 | c.1803A>T p.L601= | Silent (SNP) | VAF 79/170 reads (46%) | catalogued as COSV100206595; called by muse, mutect2, varscan2
- PRDM9 | c.1812G>T p.G604= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV99690546; called by muse, varscan2
- PTPN9 | c.1032G>C p.V344= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as COSV100144354; called by muse, mutect2, varscan2
- RDH11 | c.813C>G p.A271= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs1459964401, COSV101191470; called by muse, mutect2, varscan2
- RFX6 | c.249T>C p.F83= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs565954659, COSV100263805; called by muse, mutect2, varscan2
- RUNX1T1 | c.1197C>A p.A399= (on ENST00000265814 / NM_001198628.1; = p.A372= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/118 reads (54%) | catalogued as COSV56139460; called by muse, mutect2, varscan2
- SCARA5 | c.96G>A p.L32= | Silent (SNP) | VAF 76/97 reads (78%) | catalogued as COSV100107926; called by muse, mutect2, varscan2
- SIN3A | c.2583C>A p.P861= | Silent (SNP) | VAF 79/173 reads (46%) | catalogued as COSV100845164; called by muse, mutect2, varscan2
- SLC17A6 | c.1494C>A p.A498= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV99581564; called by muse, mutect2, varscan2
- SLC26A3 | c.123G>T p.V41= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV100385103; called by muse, mutect2, varscan2
- SNTG1 | c.507C>G p.L169= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV99383998; called by muse, mutect2, varscan2
- STEAP4 | c.255T>C p.H85= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as COSV100112597; called by muse, mutect2
- SYNE1 | c.4998C>A p.S1666= (on ENST00000367255 / NM_182961.4; = p.S1673= on NM_033071.3) | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs1247706511, COSV99566586; called by muse, mutect2, varscan2
- TERT | c.282G>A p.K94= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99718713; called by muse, mutect2, varscan2
- TUBGCP2 | c.2442G>C p.L814= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99427832; called by muse, mutect2
- XRN1 | c.4962G>A p.L1654= | Silent (SNP) | VAF 58/99 reads (59%) | catalogued as COSV99378143; called by muse, mutect2, varscan2
- ZNF587 | c.1584C>T p.S528= | Silent (SNP) | VAF 43/126 reads (34%) | catalogued as rs1251346888, COSV100299512; called by muse, mutect2, varscan2
- ZNF671 | c.1059C>A p.I353= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as COSV100235074; called by muse, mutect2, varscan2
- ZNF804A | c.2220T>A p.V740= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100168235; called by muse, mutect2
- ZNF804A | c.3573C>T p.L1191= | Silent (SNP) | VAF 128/284 reads (45%) | catalogued as COSV100168238, COSV56437929; called by muse, mutect2, varscan2
- EEF1D | c.-7-2207C>T | Intron (SNP) | VAF 21/32 reads (66%) | catalogued as rs762495668, COSV100414795; called by muse, mutect2, varscan2
- HMGB1P1 | n.457G>C | RNA (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- SAMD14 | c.823-60G>C | Intron (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99142971; called by muse, mutect2, varscan2
- SNORD116-21 | n.86G>A | RNA (SNP) | VAF 74/162 reads (46%) | called by muse, mutect2, varscan2
